Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7309, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7309-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

Physician(s): [REDACTED]

Phy Locat [REDACTED]

=====

CLINICAL HISTORY

Left frontal tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, tumor, biopsy

B: Residual tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, left frontal tumor, excision biopsy: Anaplastic
oligodendroglioma

WHO Grade (III) (see comment).

B. Brain, residual tumor, excision biopsy: Cerebral tissue with
sparse
infiltrating oligodendroglioma cells (see comment).

COMMENT

Permanent sections of A confirm the frozen section diagnosis. Sections
show a

mild to moderately pleomorphic glioma with mostly round to oval
nuclei. Focal

dense cellularity, occasional mitoses and early microvascular
proliferation

are noted. The tumor is diffusely GFAP positive, highlighting numerous
gliofibrillary oligodendrocytes. The Ki-67 labeling index is
approximately up

to 5%. Sections of B show mostly white matter with rare to occasional
enlarged

atypical cells that positive for Ki-67.

This tumor shows mostly oligodendroglial features but shows some
pleomorphism

consistent with the "polymorphic variant of Zulch" type of
oligodendroglioma,

[page 2 of 5]
usually considered grade III. There may also be a minor astrocytic component.

Results of additional ancillary studies will be reported below in procedure addenda.

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay

Date Ordered: Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S552, D19S412, D19S606 and D19S1182

Results-Comments

Testing performed on DNA extracted from tumor paraffin block. DNA extracted from a corresponding blood specimen was used as a normal reference control.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the as

[page 3 of 5]
required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the AP Molecular Pathology laboratory as required by [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

[page 4 of 5]
determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, tumor, biopsy: Glioma with oligodendroglial features, recommend collect blood for LOH studies. Frozen section and smears performed at [REDACTED] and results reported to the Physician of Record.

[REDACTED]

[REDACTED]

Senior Staff Pathologist

GROSS DESCRIPTION

A. Brain, tumor, biopsy:
CONTAINER LABEL: TUMOR.
FIXATIVE: Formalin. NO. PIECES: multiple. SIZE/VOL: 40x 15x 3 mm.
CASSETTES: 1- frozen section remnant, 2 and 3 remaining, [REDACTED]

B. Residual tumor, excision biopsy:
CONTAINER LABEL: residual tumor.
FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 20x 13x 4 mm.
CASSETTES: 2,
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

ICD-9(s):
239.6 239.6
Billing Fee Code(s):

[REDACTED]

Histo Data

Part A: Brain, tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
mGFAP-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
LOH-curles x 1	2	[REDACTED]	
MGMT-curles x 1	2	[REDACTED]	

[page 5 of 5]
MIB1-DA x 1 2
Rct 1 H/E x 1 2
Rct 1 H/E x 1 2
H/E x 1 3

Part B: Residual tumor, excision biopsy

Taken:		Received:	
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
MIB1-DA x 1	1		
H/E x 1	2		
MIB1-DA x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 6cf9c50c-7892-4f55-b7b4-b76b1df5503c (TCGA-DU-7309.0B731266-908E-477B-8228-99D3F1D510E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).